Gene-level copy-number profile of tumor specimen REBC-ACBV-TTP1-A from REBC case REBC-ACBV, project REBC-THYR (Comprehensive genomic characterization of radiation-related papillary thyroid cancer in the Ukraine). Sex at birth: male; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland.
Specimen REBC-ACBV-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 61b3571d-2105-4e71-8a9a-c685d5ab1cf6.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator REBC-ACBV-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,740 have no estimate.
https://portal.gdc.cancer.gov/files/93ce607e-df5a-44d0-9575-49c9034e1ee2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 22; copy number 1: 2,960; copy number 2: 55,756; copy number 3: 145.

Homozygous deletions (total copy number 0; autosomes only): 22 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:16,687,339–16,972,964, 13 genes (within-gene range 0–2): ESPNP, AL021920.1, AL021920.3, CROCC, CROCCP4, RNU1-4, MST1L, BX284668.1, BX284668.3, MIR3675, BX284668.2, RNU1-5P, BX284668.5.
- chr1:16,895,980–16,904,776, 2 genes (within-gene range 0–2): RNU1-2, BX284668.6.
- chr10:14,061–74,163, 3 genes: AC215217.1, AL713922.1, TUBB8.
- chr21:8,603,547–8,761,335, 4 genes: RPSAP68, CR381572.2, CR381572.1, LINC01666.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 104. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
